TCGA case TCGA-KQ-A41O — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Cornell Medical College. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9dd41965-7a62-464d-8a23-5c3f9565dd91

Demographics
Sex at birth: male; Country of residence at enrollment: United States; Age at index: 84 years; Vital status: Alive.

Diagnoses (3)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 84.3 years (30,774 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: Yes; Lymph nodes positive: 2; Lymph nodes tested: 12; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 78.3 years (28,614 days); Days to diagnosis: -2,160 days (-5.9 years); AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,160 days (-5.9 years); Treatment anatomic sites: Bladder.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Days to treatment start: -2,136 days (-5.8 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Radiation Therapy, NOS.
3. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Timepoint category: Prior to Procurement.

Follow-up (1 entry)
- Days to follow up: 1,538 days (4.2 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 50 kg; Height: 163 cm; BMI: 18.8.

Exposures
- Chemical exposure type: Pesticide; Occupation type: Mixed Crop and Animal Producers.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1946.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KQ-A41O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 800 mg.
  Slide TCGA-KQ-A41O-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Samples TCGA-KQ-A41O-10D, TCGA-KQ-A41O-10E (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation primary: Farmer; Occupation primary chemical exposure: Pesticide; Occupation primary industry: Agriculture; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Neck; Anatomic organ subdivision: Trigone; Anatomic organ subdivision: Wall Anterior; Anatomic organ subdivision: Wall Lateral; Anatomic organ subdivision: Wall Posterior; Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Bacillus Calmette-Guerin (BCG); Bcg treatment 90 days prior to resection: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: urothelial carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Transurethral resection of bladder.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Locoregional.
- Other malignancy form, Drug treatment, Administered drug: Pharmaceutical therapy drug name: BCG.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,538 days; disease-specific survival: no event (censored), 1,538 days; progression-free interval: no event (censored), 1,538 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KQ-A41O-01A-12D-A34T-01): tumor purity 0.93, ploidy 3.76, whole-genome doublings 1.
